Gene-level copy-number profile of tumor specimen TARGET-40-PALKDP-01A from TARGET case TARGET-40-PALKDP, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 9.3 years (3,388 days).
Specimen TARGET-40-PALKDP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.d265b316-a594-546f-908e-d3fb60935b5e.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PALKDP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 467 have no estimate.
https://portal.gdc.cancer.gov/files/17400b58-7cc7-41bb-b50d-4a03e404c712

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 575; copy number 1: 908; copy number 2: 14,739; copy number 3: 15,657; copy number 4: 21,289; copy number 5: 2,302; copy number 6: 2,928; copy number 7: 788; copy number 8: 399; copy number 9: 32; copy number 10: 30; copy number 11: 139; copy number 12: 245; copy number 15: 11; copy number 17: 7; copy number 19: 61; copy number 23: 9; copy number 26: 16; copy number 34: 19; copy number 39: 2.

Homozygous deletions (total copy number 0; autosomes only): 55 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,614,098, 2 genes: LCE3C, LCE3B.
- chr2:199,457,700–199,750,341, 3 genes: SATB2-AS1, LINC01877, SEPHS1P6.
- chr2:212,426,263–212,426,360, 1 gene: MIR548F2.
- chr5:165,129,307–166,926,370, 10 genes: AC091973.1, LINC01938, AC008415.1, RN7SKP60, AC008562.1, AC008489.1, RPL7P20, AC114321.1, AC026403.1, LINC01947.
- chr5:167,287,320–167,309,870, 3 genes: AC091820.2, AC091820.1, AC008601.1.
- chr7:147,080,934–147,167,572, 3 genes: CNTNAP2-AS1, DUTP3, RANP2.
- chr9:61,581,813–61,642,494, 3 genes: AL935212.3, FAM242D, Y_RNA.
- chr11:84,997,226–85,021,655, 2 genes: AP000857.1, HNRNPCP6.
- chr16:73,092,349–73,294,296, 4 genes: HCCAT5, AC116667.2, AC140912.1, AC009033.1.
- chr16:86,474,529–86,555,235, 5 genes (within-gene range 0–2): FENDRR, FOXF1, AC009108.3, AC009108.1, MTHFSD.
- chr17:7,646,627–7,833,744, 6 genes (within-gene range 0–2): ATP1B2, TP53, WRAP53, EFNB3, DNAH2, RPL29P2.
- chr17:8,965,896–8,976,995, 2 genes: AC002091.2, AC002091.1.
- chr17:9,244,666–9,645,325, 10 genes: AC005695.3, STX8, AC005695.2, AC087501.1, AC087501.2, AC087501.3, AC087501.4, CFAP52, RPL19P18, AC118755.2.
- chr17:9,647,020–9,647,660, 1 gene: AC118755.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 571 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–152,580,516, 362 genes, copy number 11–12 (broad region; genes not listed).
- chr1:152,622,834–152,911,886, 22 genes, copy number 12: LCE3A, LCEP4, LCEP3, LCE2D, LCE2C, LCE2B, LCE2A, LCE4A, C1orf68, LCEP2, LCEP1, KPRP, LCE1F, LCE1E, LCE1D, LCE1C, LCE1B, LCE1A, LCE6A, AL162596.1, SMCP, IVL.
- chr2:96,760,902–97,094,882, 22 genes, copy number 9 (within-gene range 6–9): CNNM4, MIR3127, CNNM3-DT, CNNM3, ANKRD23, ANKRD39, SEMA4C, FAM178B, AC092636.1, Metazoa_SRP, RNA5SP101, AC079395.3, AC079395.2, AC079395.1, TRIM43CP, AC018892.1, AC018892.2, IGKV2OR2-1, IGKV2OR2-2, IGKV1OR2-3, GPAT2P2, FAHD2B.
- chr3:66,133,610–66,637,412, 6 genes, copy number 9: SLC25A26, RNU6-787P, RN7SL482P, LRIG1, AC104440.1, RPL21P41.
- chr3:69,999,550–70,518,064, 4 genes, copy number 9 (within-gene range 6–9): SAMMSON, AC139700.1, UQCRHP4, MDFIC2.
- chr3:73,382,431–75,085,237, 12 genes, copy number 10: PDZRN3, RNU7-119P, PDZRN3-AS1, AC117489.1, AC108725.1, LINC02005, Metazoa_SRP, LINC02047, AC016930.1, AKR1B1P2, CNTN3, NIPA2P2.
- chr11:101,765,935–102,966,628, 37 genes, copy number 26–39: AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3.
- chr11:106,674,019–107,666,779, 12 genes, copy number 17–23: GUCY1A2, AP001282.2, AP001282.1, ASS1P13, AP000766.1, CWF19L2, SMARCE1P1, ALKBH8, AP001823.1, ELMOD1, AP000889.2, AP000889.1.
- chr11:110,788,026–111,040,208, 4 genes, copy number 23: HNRNPA1P60, AP002963.1, AP003973.4, RNA5SP350.
- chr13:110,762,674–114,337,626, 90 genes, copy number 10–19 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 221. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
